Somatic mutation profile of tumor specimen TCGA-61-1900-01A (aliquot TCGA-61-1900-01A-01W-0639-09) from TCGA case TCGA-61-1900, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 51.9 years (18,963 days).
Specimen TCGA-61-1900-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1b7b7db-132e-40d1-8ba4-d874b4c15145.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1900-11A (Solid Tissue Normal), aliquot TCGA-61-1900-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0e1525b-865d-4406-93bd-b1b04ef71b31

The open-access MAF lists 103 somatic variants for this specimen: 82 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 16, Frame Shift Del 9, Nonsense Mutation 5, Splice Site 5, In Frame Del 3, Intron 3, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.493-2A>C p.X165_splice | Splice Site (SNP) | VAF 17/151 reads (11%) | catalogued as rs587781784, CS075218, COSV64297091, COSV64308401; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV72207688; called by muse, mutect2, varscan2
- ACTRT2 | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV65760677; called by muse, mutect2, varscan2
- ADAM7 | c.1183T>C p.F395L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51547200; called by muse, mutect2, varscan2
- ADAMTS4 | c.2140G>T p.V714F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV63490579, COSV63491319; called by muse, mutect2, varscan2
- CDH20 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 111/256 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs1247983365, COSV53018991; called by muse, mutect2, varscan2
- CGN | c.3045C>A p.D1015E | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54970744, COSV54974125; called by muse, mutect2, varscan2
- CHI3L2 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs996353137, COSV63874997; called by muse, mutect2, varscan2
- CSF2RB | c.2395C>G p.R799G | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV53261337; called by muse, mutect2, varscan2
- CSRNP1 | c.1747C>G p.L583V | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.319); catalogued as COSV56190152; called by muse, mutect2, varscan2
- CSTF2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV65895082; called by muse, mutect2
- CTNND2 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1329443102, COSV58886074; called by muse, mutect2
- DNAH1 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV70237183; called by muse, mutect2, varscan2
- DPP10 | c.733T>C p.S245P | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59698311; called by muse, mutect2, varscan2
- DYSF | c.6044T>G p.L2015R | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50627123; called by muse, mutect2, varscan2
- FAM47C | c.2933G>A p.G978E | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1569417638; called by muse, mutect2
- FLG2 | c.7118A>T p.N2373I | Missense Mutation (SNP) | VAF 18/435 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101166274; called by muse, mutect2
- FNDC3A | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 114/193 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs372893646; called by muse, mutect2, varscan2
- FRMD4B | c.1547C>G p.A516G | Missense Mutation (SNP) | VAF 63/99 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68333882; called by muse, mutect2, varscan2
- GDA | c.798T>G p.D266E | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs1272226659, COSV52994626, COSV52998263; called by muse, mutect2, varscan2
- GOLGB1 | c.6278G>A p.R2093K | Missense Mutation (SNP) | VAF 10/324 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs1166428630; called by muse, mutect2
- GPAA1 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs374430537; called by muse, mutect2, varscan2
- GPRASP1 | c.2127G>T p.W709C | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100851090; called by muse, mutect2
- H4C3 | c.124G>C p.G42R | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58091586; called by muse, mutect2, varscan2
- HECW1 | c.3669C>A p.Y1223* | Nonsense Mutation (SNP) | VAF 72/144 reads (50%) | catalogued as COSV67841077; called by muse, mutect2, varscan2
- HUWE1 | c.9120G>T p.E3040D | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53366033; called by muse, mutect2, varscan2
- HUWE1 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.352); catalogued as COSV53340914, COSV53366052; called by muse, mutect2, varscan2
- IGHV1-18 | c.61G>T p.V21F | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs578104719; called by muse, mutect2
- INPP5D | c.2026C>A p.L676I (on ENST00000445964 / NM_001017915.3; = p.L675I on NM_005541.5) | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64040837; called by muse, mutect2, varscan2
- IRAK4 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV71211036; called by muse, mutect2, varscan2
- KCNH5 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59779928; called by muse, mutect2, varscan2
- LAS1L | c.557G>C p.C186S | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV56709220; called by muse, mutect2, varscan2
- LIN7A | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as rs763460890, COSV54024877; called by muse, mutect2, varscan2
- LTN1 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 116/264 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs1221350872, COSV100798034, COSV63735470; called by muse, mutect2, varscan2
- MACF1 | c.17196_17222del p.F5732_T5741delinsL (on ENST00000372915; = p.F3774_T3783delinsL on NM_012090.5) | In Frame Del (DEL) | VAF 8/62 reads (13%) | catalogued as COSV57147059; called by mutect2, pindel, varscan2
- MEIOB | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58056043; called by muse, mutect2, varscan2
- MON2 | c.1409T>A p.M470K | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV54816003; called by muse, mutect2, varscan2
- NONO | c.1342G>T p.G448C | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV52140654; called by muse, mutect2, varscan2
- NRXN3 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.031); catalogued as COSV55358884, COSV99821129; called by muse, mutect2, varscan2
- OLFM4 | c.1061C>A p.T354N | Missense Mutation (SNP) | VAF 114/363 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.104); catalogued as COSV54580799; called by muse, mutect2, varscan2
- OR14I1 | c.450C>A p.C150* | Nonsense Mutation (SNP) | VAF 51/89 reads (57%) | catalogued as COSV61198905; called by muse, mutect2, varscan2
- OR2T3 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.339); catalogued as COSV100613413, COSV62082147; called by muse, mutect2, varscan2
- OXA1L | c.1158_1182del p.L387Ffs*28 (on ENST00000285848; = p.L327Ffs*28 on NM_005015.5) | Frame Shift Del (DEL) | VAF 56/170 reads (33%) | catalogued as COSV53538639; called by mutect2, pindel, varscan2
- P3H4 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1555614942, COSV58636582, COSV58639488; called by muse, mutect2, varscan2
- PASD1 | c.1594C>A p.L532M | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.557); catalogued as rs778716098, COSV64855143; called by muse, mutect2, varscan2
- PGC | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV62678384; called by muse, mutect2, varscan2
- PLG | c.1582A>T p.K528* | Nonsense Mutation (SNP) | VAF 84/106 reads (79%) | catalogued as COSV51986809; called by muse, mutect2, varscan2
- PLK4 | c.2153C>A p.S718Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV54639653; called by muse, mutect2, varscan2
- PPP1CB | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56092176; called by muse, mutect2, varscan2
- PSMD7 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV54698782; called by muse, mutect2, varscan2
- RCOR2 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100036400; called by muse, mutect2
- SFI1 | c.2261T>C p.L754P (on ENST00000400288 / NM_001007467.3; = p.L723P on NM_014775.4) | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63476016; called by mutect2, varscan2
- SIK3 | c.2524C>G p.Q842E (on ENST00000445177 / NM_001366686.2; = p.Q800E on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); catalogued as COSV52623949; called by muse, mutect2, varscan2
- SLC25A12 | c.440A>T p.Y147F | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV99785509; called by muse, mutect2, varscan2
- SLC25A12 | c.439T>C p.Y147H | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99785512; called by muse, mutect2, varscan2
- STRN | c.2115C>A p.H705Q | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99815772; called by muse, mutect2
- SYNJ1 | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59157500; called by muse, mutect2, varscan2
- TENT4A | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1470863189, COSV50102807; called by muse, mutect2, varscan2
- TFB2M | c.1057C>G p.Q353E | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.42); PolyPhen benign (0.077); catalogued as rs770783486, COSV63624924; called by muse, mutect2, varscan2
- TMEM9B | c.468C>A p.H156Q | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as COSV58428291; called by muse, mutect2, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 182/282 reads (65%) | catalogued as rs587780067; called by pindel, varscan2
- TTN | c.56993A>T p.Y18998F (on ENST00000591111; = p.Y11574F on NM_003319.4) | Missense Mutation (SNP) | VAF 74/228 reads (32%) | PolyPhen benign (0); catalogued as COSV60382294; called by muse, mutect2, varscan2
- TTYH2 | c.731+1G>C p.X244_splice | Splice Site (SNP) | VAF 20/61 reads (33%) | catalogued as COSV53913842, COSV99074489; called by muse, mutect2, varscan2
- USH2A | c.3428C>A p.T1143K | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56446101; called by muse, mutect2, varscan2
- USP9X | c.1054A>G p.M352V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61075954; called by muse, mutect2, varscan2
- WDR33 | c.355A>T p.K119* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV59256151; called by muse, mutect2, varscan2
- ZNF16 | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV52765901; called by muse, mutect2, varscan2
- ZNF669 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs563768242, COSV58539602; called by muse, mutect2, varscan2
- ZNF804A | c.255+1G>C p.X85_splice | Splice Site (SNP) | VAF 38/149 reads (26%) | catalogued as COSV100166852, COSV56473742; called by muse, mutect2, varscan2
- CYP2E1 | c.968-3_984delinsG p.X323_splice | Splice Site (DEL) | VAF 11/23 reads (48%) | called by pindel, varscan2*
- FCRLA | c.105_125del p.W37_L43del (on ENST00000367959; = p.W20_L26del on NM_032738.4) | In Frame Del (DEL) | VAF 36/124 reads (29%) | called by mutect2, pindel
- FSHR | c.1641_1666del p.C548Afs*10 | Frame Shift Del (DEL) | VAF 32/157 reads (20%) | called by mutect2, pindel, varscan2
- NAIP | c.172_202del p.R58* | Frame Shift Del (DEL) | VAF 40/104 reads (38%) | called by mutect2, pindel, varscan2
- OR2T34 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 51/646 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.339); called by muse, mutect2
- ROBO1 | c.2197_2215del p.K733Lfs*44 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- SNX20 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by mutect2, varscan2
- STAT6 | c.316_335del p.E106Tfs*19 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- TAL2 | c.99_101del p.P34del | In Frame Del (DEL) | VAF 24/55 reads (44%) | called by mutect2, pindel, varscan2
- TBX19 | c.1158_1173del p.A387Lfs*22 | Frame Shift Del (DEL) | VAF 12/95 reads (13%) | called by mutect2, pindel
- UBAP2 | c.2337_2371+13del p.X779_splice | Splice Site (DEL) | VAF 18/22 reads (82%) | called by mutect2, pindel
- USP29 | c.1039_1056delinsTTAA p.K347Lfs*4 | Frame Shift Del (DEL) | VAF 45/109 reads (41%) | called by pindel, varscan2*
- WDR48 | c.1509_1525del p.N504Afs*10 | Frame Shift Del (DEL) | VAF 26/152 reads (17%) | called by mutect2, pindel, varscan2
- CACNA2D3 | c.1365T>A p.A455= | Silent (SNP) | VAF 62/220 reads (28%) | catalogued as COSV55586020; called by muse, mutect2, varscan2
- CDC5L | c.525A>G p.Q175= | Silent (SNP) | VAF 252/633 reads (40%) | catalogued as rs370065367, COSV65177426; called by muse, mutect2, varscan2
- CFAP100 | c.1257C>T p.S419= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100729469; called by muse, mutect2
- CREB3L2 | c.171C>G p.L57= | Silent (SNP) | VAF 33/164 reads (20%) | catalogued as COSV57800696; called by muse, mutect2, varscan2
- HNRNPL | c.1761C>T p.H587= | Silent (SNP) | VAF 83/167 reads (50%) | catalogued as rs748201091, COSV55490515; called by muse, mutect2, varscan2
- LPIN1 | c.180C>G p.S60= | Silent (SNP) | VAF 31/51 reads (61%) | catalogued as COSV56771593; called by muse, mutect2, varscan2
- LRIG1 | c.1941C>A p.R647= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as COSV56249037; called by muse, mutect2, varscan2
- MAGI2 | c.3297G>A p.R1099= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV62702220; called by muse, mutect2, varscan2
- RPGRIP1 | c.2649C>A p.G883= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV52858234; called by muse, mutect2, varscan2
- SERINC3 | c.997C>T p.L333= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV54858693; called by muse, mutect2, varscan2
- SIX1 | c.609C>T p.L203= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV55961327, COSV55961423; called by muse, mutect2, varscan2
- SLC22A6 | c.273C>T p.L91= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV64561222; called by muse, mutect2, varscan2
- TAOK2 | c.1128C>T p.D376= | Silent (SNP) | VAF 77/177 reads (44%) | catalogued as COSV54241781; called by muse, mutect2, varscan2
- TFCP2L1 | c.1080C>T p.N360= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs372397557; called by muse, mutect2, varscan2
- TSC1 | c.2010C>A p.P670= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV53774053; called by muse, mutect2, varscan2
- ZFP57 | c.408T>A p.T136= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV65307153; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827273 C>A | 3'Flank (SNP) | VAF 89/216 reads (41%) | called by muse, mutect2, varscan2
- CEP295 | c.5851-197G>A | Intron (SNP) | VAF 33/94 reads (35%) | catalogued as rs1272218581, COSV57359522; called by muse, mutect2, varscan2
- CTBP2 | c.58+11527C>G | Intron (SNP) | VAF 25/65 reads (38%) | catalogued as COSV58346870; called by muse, mutect2, varscan2
- MROH8 | chr20:37160098 T>G | 5'Flank (SNP) | VAF 3/18 reads (17%) | catalogued as COSV54119600, COSV99458035; called by muse, mutect2
- WIPF3 | c.1428+25_1428+51del | Intron (DEL) | VAF 48/169 reads (28%) | called by mutect2, pindel, varscan2
